Somatic mutation profile of tumor specimen TCGA-CZ-5987-01A (aliquot TCGA-CZ-5987-01A-11D-1669-08) from TCGA case TCGA-CZ-5987, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 60.0 years (21,928 days).
Specimen TCGA-CZ-5987-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed1151bc-d793-41ff-8ecc-37163cd3d5a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5987-11A (Solid Tissue Normal), aliquot TCGA-CZ-5987-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9663377-d1ba-4afa-9f3d-413fc26daf5d

The open-access MAF lists 55 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 34, Silent 12, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559429824, CD962181, CM114581, CM951299, CM982013, COSV56546651, COSV56549626, COSV56559142, COSV56568527; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.2393A>C p.E798A | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV62789475; called by muse, mutect2, varscan2
- ABCC10 | c.1183G>C p.A395P (on ENST00000372530 / NM_001198934.2; = p.A352P on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV55085979; called by muse, mutect2, varscan2
- AGPS | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51562371, COSV51565468; called by muse, mutect2, varscan2
- ARFGEF2 | c.577A>T p.I193F | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64211429; called by muse, mutect2, varscan2
- ATP1A2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM082492, COSV63403044; called by muse, mutect2, varscan2
- BAZ2B | c.1848A>C p.E616D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV58597837; called by muse, mutect2, varscan2
- CA14 | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs1422894054, COSV64257341; called by muse, mutect2
- CADM3 | c.593T>G p.V198G (on ENST00000368125 / NM_001127173.3; = p.V232G on NM_021189.5) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV63684704; called by muse, mutect2, varscan2
- CATSPER1 | c.772C>A p.R258S | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56409649; called by muse, mutect2, varscan2
- CDH22 | c.1900G>A p.V634I | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs749043438, COSV64836992; called by muse, mutect2
- CNOT11 | c.1448G>C p.R483T | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56819440; called by muse, mutect2, varscan2
- DAPK1 | c.2455G>T p.V819L | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV63786192; called by muse, mutect2, varscan2
- DENND1A | c.2984C>A p.P995Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.174); catalogued as COSV65348678; called by muse, mutect2, varscan2
- ESF1 | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.255); catalogued as COSV52519998; called by muse, mutect2, varscan2
- GRM3 | c.1534C>A p.P512T | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64469265; called by muse, mutect2, varscan2
- HEPACAM2 | c.533T>C p.L178P (on ENST00000394468 / NM_001039372.4; = p.L166P on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV59059137; called by muse, mutect2, varscan2
- KIAA1614 | c.3109C>T p.P1037S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as COSV62550618; called by muse, mutect2, varscan2
- KIF19 | c.2327C>A p.T776N | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV63429148; called by muse, mutect2, varscan2
- LRRCC1 | c.2214A>G p.I738M | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.195); catalogued as COSV64483032; called by muse, mutect2, varscan2
- MTOR | c.4356A>T p.K1452N | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63869586; called by muse, mutect2, varscan2
- OSMR | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57083140; called by muse, mutect2, varscan2
- PDCD6IP | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 59/101 reads (58%) | catalogued as COSV56242361; called by muse, mutect2, varscan2
- PRDM14 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1355431485, COSV52571347; called by muse, mutect2
- PRRC2A | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV63224421; called by muse, mutect2, varscan2
- PZP | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV54354474; called by muse, mutect2, varscan2
- RAPGEFL1 | c.681G>C p.L227F | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52862765; called by muse, mutect2, varscan2
- RYR3 | c.11633T>C p.L3878P (on ENST00000389232; = p.L3879P on NM_001036.6) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66782837; called by muse, mutect2, varscan2
- RYR3 | c.12733G>A p.D4245N (on ENST00000389232; = p.D4246N on NM_001036.6) | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV66782841; called by muse, mutect2, varscan2
- SLA2 | c.262del p.A88Pfs*12 | Frame Shift Del (DEL) | VAF 49/185 reads (26%) | catalogued as COSV53413057; called by mutect2, pindel, varscan2
- SSH2 | c.2294A>G p.Q765R | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as rs774018278, COSV52168993; called by muse, mutect2, varscan2
- SUCLG2 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56203740; called by muse, mutect2, varscan2
- TRAPPC6A | c.470C>T p.P157L (on ENST00000585934 / NM_001270891.2; = p.P171L on NM_024108.3) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs146982912; called by muse, mutect2, varscan2
- TUBAL3 | c.1066A>G p.T356A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs181652174, COSV66814099; called by muse, mutect2, varscan2
- UBE2D1 | c.399-1G>T p.X133_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | catalogued as COSV64218245; called by muse, mutect2, varscan2
- USP48 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379678, COSV57608529; called by muse, mutect2, varscan2
- VPS8 | c.2269G>A p.E757K (on ENST00000625842 / NM_001349294.1; = p.E755K on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.388); catalogued as COSV54982626; called by muse, mutect2, varscan2
- ZNF233 | c.477A>G p.I159M | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61933439; called by muse, mutect2, varscan2
- CPNE7 | c.1521del p.A508Pfs*8 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- PBRM1 | c.128dup p.V44Cfs*9 | Frame Shift Ins (INS) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- PLCE1 | c.5332dup p.Q1778Pfs*42 | Frame Shift Ins (INS) | VAF 35/104 reads (34%) | called by mutect2, pindel, varscan2
- THOC5 | c.1487_1489+2del p.X496_splice | Splice Site (DEL) | VAF 60/237 reads (25%) | called by mutect2, pindel, varscan2
- UTP20 | c.7819_7822del p.E2607Rfs*2 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by pindel, varscan2
- ACACB | c.66C>A p.I22= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as COSV58131148; called by muse, mutect2, varscan2
- ACSM4 | c.624C>T p.F208= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs770046219, COSV68067333; called by muse, mutect2, varscan2
- CDH7 | c.441C>T p.N147= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs143932384, COSV100543517; called by muse, mutect2, varscan2
- DCLK2 | c.1947C>A p.P649= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV56201672; called by muse, mutect2, varscan2
- FGFR2 | c.102G>A p.E34= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV60643423; called by muse, mutect2, varscan2
- IRX5 | c.276C>A p.G92= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV58058702; called by muse, mutect2, varscan2
- KRT37 | c.666C>T p.A222= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs559004919, COSV56657435, COSV56658460; called by muse, mutect2, varscan2
- MYG1 | c.72C>T p.R24= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV54475517; called by muse, mutect2, varscan2
- PRKCA | c.1149C>T p.C383= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as COSV52581473; called by muse, mutect2, varscan2
- RPS18 | c.36T>C p.I12= | Silent (SNP) | VAF 94/165 reads (57%) | catalogued as COSV71403437; called by muse, mutect2, varscan2
- SH2D1B | c.357A>C p.T119= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV63392112; called by muse, mutect2, varscan2
- SWT1 | c.708C>T p.I236= | Silent (SNP) | VAF 76/229 reads (33%) | catalogued as rs1264533124, COSV62253980; called by muse, mutect2, varscan2
